MMRF case MMRF_1861 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/01d7d3ec-10b6-4d78-b8ff-2c089bbc3d6e

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.0 years (26,303 days); ISS stage: I; Days to last known disease status: 997 days (2.7 years); Days to last follow up: 997 days (2.7 years).
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 123 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 77 days.
   Treatment given: Therapeutic agents: Prednisone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 252 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 102 days; Days to treatment end: 252 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 130 days; Days to treatment end: 270 days.
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,040 days (2.8 years); Days to treatment end: 1,067 days (2.9 years).
   Treatment given: Therapeutic agents: Dexamethasone + Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 1,068 days (2.9 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -4: M Protein 1.76 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.81 mg/dL; Immunoglobulin G 20.9 g/L; Immunoglobulin A 0.32 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 3.01 µg/mL; Lactate Dehydrogenase 2.88 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 3.6 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 161 ×10⁹/L; Creatinine 53 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.38 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 6.27 mmol/L; C-Reactive Protein 0.02 mg/dL.
- Day 102: M Protein 0.34 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.733 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 5.47 g/L; Immunoglobulin A 0.33 g/L; Immunoglobulin M 0.57 g/L; Beta 2 Microglobulin 2.23 µg/mL; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 68 ×10⁹/L; Creatinine 47.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.43 mmol/L; Albumin 44 g/L; Total Protein 6.1 g/dL; Glucose 5.67 mmol/L.
- Day 186: M Protein 0.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.742 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.921 mg/dL; Immunoglobulin G 5.77 g/L; Immunoglobulin A 0.48 g/L; Immunoglobulin M 0.65 g/L; Beta 2 Microglobulin 2.06 µg/mL; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 6 g/dL; Glucose 5.28 mmol/L.
- Day 249: M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.903 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.987 mg/dL; Immunoglobulin G 6.25 g/L; Immunoglobulin A 0.53 g/L; Immunoglobulin M 0.69 g/L; Beta 2 Microglobulin 2.22 µg/mL; Lactate Dehydrogenase 3.18 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 79 ×10⁹/L; Creatinine 51.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.43 mmol/L; Albumin 42 g/L; Total Protein 6.2 g/dL; Glucose 5.89 mmol/L.
- Day 353 (ECOG 0): M Protein 0.36 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.889 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.09 mg/dL; Immunoglobulin G 8.51 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 0.92 g/L; Beta 2 Microglobulin 1.63 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.56 mmol/L; Leukocytes 7.1 ×10⁹/L; Absolute Neutrophil 5.7 ×10⁹/L; Platelets 134 ×10⁹/L; Creatinine 56.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.53 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 5.34 mmol/L.
- Day 437 (ECOG 0): M Protein 0.31 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.682 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.23 mg/dL; Immunoglobulin G 8.16 g/L; Immunoglobulin A 0.82 g/L; Immunoglobulin M 1.35 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.65 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 8.6 ×10⁹/L; Absolute Neutrophil 6.8 ×10⁹/L; Platelets 127 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 46 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 549 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.76 mg/dL; Immunoglobulin G 7.65 g/L; Immunoglobulin A 0.95 g/L; Immunoglobulin M 1.5 g/L; Beta 2 Microglobulin 1.87 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 8.74 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 137 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.48 mmol/L; Albumin 45 g/L; Total Protein 6.6 g/dL; Glucose 5.39 mmol/L.
- Day 605 (ECOG 0): M Protein 0.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.822 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.992 mg/dL; Immunoglobulin G 7.99 g/L; Immunoglobulin A 0.93 g/L; Immunoglobulin M 1.56 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 2.55 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 3.7 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.5 mmol/L; Albumin 44 g/L; Total Protein 6.5 g/dL; Glucose 5.5 mmol/L.
- Day 717 (ECOG 0): M Protein 0.53 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.23 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.11 mg/dL; Immunoglobulin G 9.21 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 1.56 g/L; Beta 2 Microglobulin 1.78 µg/mL; Lactate Dehydrogenase 2.85 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.6 ×10⁹/L; Platelets 121 ×10⁹/L; Creatinine 61 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.43 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 5.94 mmol/L.
- Day 801 (ECOG 0): M Protein 0.75 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.14 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.24 mg/dL; Immunoglobulin G 10.6 g/L; Immunoglobulin A 1.11 g/L; Immunoglobulin M 1.43 g/L; Beta 2 Microglobulin 1.7 µg/mL; Lactate Dehydrogenase 3.4 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 100 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.45 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 6 mmol/L.
- Day 913 (ECOG 1): M Protein 1.38 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.11 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 6.95 mg/dL; Immunoglobulin G 18.7 g/L; Immunoglobulin A 1.13 g/L; Immunoglobulin M 1.33 g/L; Beta 2 Microglobulin 3.23 µg/mL; Lactate Dehydrogenase 3.12 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 111 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.33 mmol/L; Albumin 39 g/L; Total Protein 7 g/dL; Glucose 5.61 mmol/L.
- Day 997: M Protein 2.28 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.84 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 12.6 mg/dL; Immunoglobulin G 29.8 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 1.13 g/L; Beta 2 Microglobulin 5.2 µg/mL; Lactate Dehydrogenase 3.9 µkat/L; Hemoglobin 9.73 mmol/L; Leukocytes 3.7 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.3 mmol/L; Albumin 35 g/L; Total Protein 7.8 g/dL; Glucose 5.89 mmol/L.

Other clinical attributes
- Day -4: Weight: 54 kg; Height: 145 cm.

Family history
- Relative with cancer history: yes; Relationship type: Sibling.
- Relative with cancer history: yes; Relationship type: Sibling; Relationship primary diagnosis: Colorectal Cancer.

Biospecimens (2 samples)
- Sample MMRF_1861_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -4 days.
- Sample MMRF_1861_1_PB_WBC: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -4 days.
